Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A4O8, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A4O8-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: THYROID GLAND, TOTAL THYROIDECTOMY (21 GRAMS) -

- A. PAPILLARY THYROID CARCINOMA, 1.5 CM, ISTHMIC, CONVENTIONAL, INFILTRATIVE (see comment).
- B. ADDITIONAL 0.3 CM FOCUS OF PAPILLARY THYROID CARCINOMA, CONFINED TO LEFT LOBE.
- C. VASCULAR INVASION IS ABSENT.
- D. MINIMAL EXTRATHYROIDAL EXTENSION IS PRESENT.
- E. CARCINOMA IS ABOUT 0.1 CM FROM MARGIN.
- F. CHRONIC LYMPHOCYTIC THYROIDITIS.
- G. PATHOLOGIC STAGE: pT3N1a.

PART 2: CENTRAL COMPARTMENT NODES, DISSECTION -

- A. METASTATIC PAPILLARY THYROID CARCINOMA, UP TO 0.2 CM, IN SIX OF FOURTEEN LYMPH NODES (6/14).
- B. EXTRACAPSULAR SPREAD IS ABSENT.

PART 3: LEFT ABDOMINAL WALL NODULE, EXCISION - **TRICHILEMMAL (PILAR) CYST, 1 CM.**

PART 4: RIGHT INFERIOR PARATHYROID, BIOPSY (8 MG) - **NORMOCELLULAR PARATHYROID.**

COMMENT:

Prior molecular testing of the right isthmus thyroid fine needle aspirated revealed BRAF p.V600E mutation

SYNOPTIC DATA - PRIMARY THYROID TUMORS

SPECIMEN TYPE:	Total Thyroidectomy
TUMOR SITE:	Left Lobe, Isthmus
TUMOR FOCALITY:	Multifocal
TUMOR SIZE (largest nodule):	Greatest Dimension: 1.5 cm
HISTOLOGIC TYPE**:	Papillary carcinoma
PRIMARY TUMOR (pT):	pT3
REGIONAL LYMPH NODES (pN):	pN1a
	Number of regional lymph nodes examined: 14
	Number of regional lymph nodes involved: 6
EXTRANODAL EXTENSION:	Not identified
DISTANT METASTASIS (pM):	Not applicable
EXTRATHYROIDAL EXTENSION:	Present
	Extent: Minimal
MARGINS:	Margins uninvolved by carcinoma
LYMPH-VASCULAR INVASION:	Not identified

ICD-0-3

carcinoma, papillary, thyroid 8260/3
Site: thyroid NOS C73.9

hw
10/7/12

HPVAA Discrepancy		

hw
9/23/12

Source: NCI Genomic Data Commons file f2dca56e-4819-4d58-9725-c263efd999d2 (TCGA-BJ-A4O8.12703516-FB7D-4C4B-BA56-5743810CB72F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).